Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3855, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3855-01A (Primary Tumor).

Diagnosis:

This material is an epiploic appendix with inflammatory reactive lesions in I),
in II) a free anastomosis
and in III) a moderately differentiated invasive adenocarcinoma of the colon with infiltration of
the muscularis and vessels (G2, pT2, L1, V1).
It also shows free resection margins and free lymph nodes (pN0)

Tumor classification:

ICDO-DA M8140/3

G2

pT2, L1, V1, pN0 (0 of 36)

Locally R0

M classification in the context of the oncology conference

Source: NCI Genomic Data Commons file f35d5c50-5b5e-4a31-8824-1d4b9f870a83 (TCGA-AA-3855.F0EEACCF-D2EB-444F-B3E8-D9D3C3663272.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).